Somatic mutation profile of tumor specimen TCGA-CJ-5675-01A (aliquot TCGA-CJ-5675-01A-11D-1534-10) from TCGA case TCGA-CJ-5675, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 70.1 years (25,617 days).
Specimen TCGA-CJ-5675-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6e13589-a179-4490-a52e-19b2bbbe14fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-5675-11A (Solid Tissue Normal), aliquot TCGA-CJ-5675-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4d5f285-2c6c-494e-8497-dcbf540c3442

The open-access MAF lists 69 somatic variants for this specimen: 53 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 40, Silent 16, Nonsense Mutation 5, Frame Shift Del 5, Frame Shift Ins 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2340A>C p.R780S | Missense Mutation (SNP) | VAF 49/189 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705753; called by muse, mutect2, varscan2
- ABCC9 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 16/260 reads (6%) | catalogued as COSV53964272, COSV99686285; called by muse, mutect2
- ABTB2 | c.2801C>T p.A934V | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs1459529652, COSV54383797; called by muse, mutect2
- ADAMTS2 | c.3145G>C p.D1049H | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); catalogued as COSV52366337; called by muse, mutect2, varscan2
- ADAMTS5 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53176373; called by muse, mutect2, varscan2
- ADAMTSL5 | c.46del p.L16Sfs*9 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | catalogued as COSV57860629; called by mutect2, pindel, varscan2
- ADCY8 | c.1759A>C p.I587L | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV53898346; called by muse, mutect2, varscan2
- ALDH8A1 | c.754C>A p.L252M | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55640464, COSV99664733, COSV99664862; called by muse, mutect2, varscan2
- ARL8B | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 122/512 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56577322; called by muse, mutect2, varscan2
- C20orf194 | c.1838C>G p.P613R | Missense Mutation (SNP) | VAF 109/495 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.847); catalogued as COSV52692337; called by muse, mutect2, varscan2
- CABLES1 | c.1117T>C p.S373P (on ENST00000256925 / NM_001100619.2; = p.S108P on NM_138375.2) | Missense Mutation (SNP) | VAF 71/315 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV56931029; called by muse, mutect2, varscan2
- CARNS1 | c.1456C>A p.Q486K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV57048023; called by muse, mutect2
- CC2D1A | c.1910G>A p.R637H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs375346936; called by muse, mutect2, varscan2
- CCDC81 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 63/254 reads (25%) | catalogued as COSV53576989; called by muse, varscan2
- CDH11 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV51753121; called by muse, mutect2, varscan2
- CREB3L4 | c.905T>A p.L302H | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV55131526; called by muse, mutect2, varscan2
- FAM83B | c.2631C>G p.F877L | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100174991, COSV60919866; called by muse, mutect2, varscan2
- FBF1 | c.136G>T p.G46C (on ENST00000586717; = p.G60C on NM_001319193.1) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs770139438, COSV59863817; called by muse, mutect2, varscan2
- FBXO42 | c.2133C>G p.Y711* | Nonsense Mutation (SNP) | VAF 45/209 reads (22%) | catalogued as COSV65044645; called by muse, mutect2, varscan2
- GGTLC1 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV53846534; called by muse, mutect2, varscan2
- KBTBD6 | c.622T>G p.S208A | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV65270972; called by muse, mutect2, varscan2
- KCTD7 | c.393C>G p.Y131* | Nonsense Mutation (SNP) | VAF 35/104 reads (34%) | catalogued as COSV51876311; called by muse, mutect2, varscan2
- LEF1 | c.560A>C p.H187P | Missense Mutation (SNP) | VAF 83/352 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54464523; called by muse, mutect2, varscan2
- MARK1 | c.546T>A p.D182E | Missense Mutation (SNP) | VAF 64/1192 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV65065943; called by muse, mutect2
- MAST4 | c.5443G>A p.A1815T (on ENST00000403625 / NM_001164664.2; = p.A1626T on NM_015183.3) | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.042); catalogued as COSV55117572; called by muse, mutect2, varscan2
- MOSPD3 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV56157836; called by muse, mutect2, varscan2
- NCOA2 | c.2278C>A p.P760T | Missense Mutation (SNP) | VAF 99/415 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.218); catalogued as COSV71763598; called by muse, mutect2, varscan2
- NDST2 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); catalogued as COSV55213052; called by muse, mutect2, varscan2
- NKTR | c.2884G>T p.G962W | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as COSV51769689; called by muse, mutect2, varscan2
- NMT1 | c.507A>C p.L169= | Splice Region (SNP) | VAF 129/488 reads (26%) | catalogued as COSV51958544; called by muse, mutect2, varscan2
- NPHP3 | c.2641A>C p.K881Q | Missense Mutation (SNP) | VAF 76/266 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV58628471; called by muse, mutect2, varscan2
- OLFML2B | c.1932G>C p.E644D | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54194696; called by muse, mutect2, varscan2
- OR2AK2 | c.851T>C p.L284P | Missense Mutation (SNP) | VAF 32/530 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63549039; called by muse, mutect2
- PCSK9 | c.1997G>A p.S666N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV53762957; called by muse, mutect2, varscan2
- PLXNA1 | c.2844C>A p.Y948* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | catalogued as COSV52522898; called by muse, mutect2
- POC1B-GALNT4 | c.1171T>A p.F391I | Missense Mutation (SNP) | VAF 93/380 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV57963158; called by muse, mutect2, varscan2
- RAI2 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as rs768853446, COSV58963311; called by muse, mutect2, varscan2
- RNLS | c.617T>C p.I206T | Missense Mutation (SNP) | VAF 56/275 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs1340229124, COSV59291046, COSV59300526; called by muse, mutect2, varscan2
- SARDH | c.1238G>C p.G413A | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100898647, COSV64103666; called by muse, varscan2
- SCN3A | c.4746C>G p.H1582Q | Missense Mutation (SNP) | VAF 34/312 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.421); catalogued as COSV51803038; called by muse, mutect2
- SDC3 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.828); catalogued as COSV59578552; called by muse, mutect2
- SRRM2 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 93/395 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57069248; called by muse, mutect2, varscan2
- TJP1 | c.291A>C p.K97N | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV62039935; called by muse, mutect2, varscan2
- TMEM267 | c.424T>A p.C142S | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV67992460; called by muse, mutect2, varscan2
- TSPAN5 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 75/242 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs772668858, COSV59874232; called by muse, mutect2, varscan2
- ZFHX3 | c.1031A>T p.N344I | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as COSV51710748, COSV51735510; called by muse, mutect2, varscan2
- ZNF763 | c.526G>A p.E176K (on ENST00000358987 / NM_001367172.2; = p.E179K on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV59687173, COSV59687255; called by muse, mutect2, varscan2
- DHX29 | c.2694_2695dup p.K899Ifs*3 | Frame Shift Ins (INS) | VAF 104/524 reads (20%) | called by mutect2, pindel, varscan2
- LHX1 | c.27del p.R9Sfs*9 | Frame Shift Del (DEL) | VAF 24/91 reads (26%) | called by mutect2, pindel, varscan2
- MADD | c.1108_1110del p.P370del | In Frame Del (DEL) | VAF 101/428 reads (24%) | called by mutect2, pindel, varscan2
- PBRM1 | c.4819del p.S1607Qfs*5 (on ENST00000296302 / NM_001366071.2; = p.S1500Qfs*5 on NM_018313.5) | Frame Shift Del (DEL) | VAF 56/186 reads (30%) | called by mutect2, pindel, varscan2
- PPP1R9A | c.3184del p.M1062Wfs*8 | Frame Shift Del (DEL) | VAF 111/514 reads (22%) | called by mutect2, pindel, varscan2
- PPP2R3B | c.478del p.A160Pfs*63 | Frame Shift Del (DEL) | VAF 87/318 reads (27%) | called by mutect2, pindel, varscan2
- ADAMTS12 | c.378C>G p.L126= | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as COSV61256816, COSV61263493; called by muse, mutect2, varscan2
- ANGPT4 | c.225C>T p.N75= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as rs574115140, COSV67920824; called by muse, varscan2
- ATP6V0A4 | c.1698C>T p.F566= | Silent (SNP) | VAF 51/246 reads (21%) | catalogued as rs367943974, COSV59473081; called by muse, mutect2, varscan2
- CCDC81 | c.123G>T p.R41= | Silent (SNP) | VAF 64/258 reads (25%) | catalogued as rs890160168, COSV53576978; called by muse, varscan2
- CSMD2 | c.1647C>T p.P549= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as rs142181378; called by muse, mutect2, varscan2
- DEPDC1 | c.1791T>G p.V597= (on ENST00000456315 / NM_001114120.3; = p.V313= on NM_017779.6) | Silent (SNP) | VAF 12/300 reads (4%) | catalogued as COSV63957617; called by muse, mutect2
- FCGBP | c.8010G>A p.G2670= | Silent (SNP) | VAF 20/179 reads (11%) | catalogued as COSV55429761; called by muse, mutect2, varscan2
- ITIH6 | c.1230C>T p.I410= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV54487029; called by muse, mutect2, varscan2
- KCNQ3 | c.2220G>A p.T740= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs758265549, COSV66464762; called by muse, mutect2, varscan2
- LILRA6 | c.927C>T p.P309= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs1232632229, COSV54430972; called by muse, mutect2, varscan2
- MDGA1 | c.2682G>A p.G894= | Silent (SNP) | VAF 44/115 reads (38%) | catalogued as COSV51792596; called by muse, mutect2, varscan2
- PARP9 | c.2217C>G p.T739= | Silent (SNP) | VAF 75/330 reads (23%) | catalogued as COSV64450108; called by muse, mutect2, varscan2
- PRRC2A | c.2385C>A p.V795= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV65685390; called by muse, mutect2, varscan2
- WDR35 | c.2007G>C p.R669= (on ENST00000345530 / NM_001006657.2; = p.R658= on NM_020779.4) | Silent (SNP) | VAF 24/352 reads (7%) | catalogued as COSV55600881; called by muse, mutect2
- ZBTB49 | c.406C>T p.L136= | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as COSV61924463; called by muse, mutect2, varscan2
- ZNF407 | c.3798T>C p.V1266= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV55244691; called by muse, mutect2, varscan2
